Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8PQ, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8PQ-01A (Primary Tumor).

TCGA-VQ-AS PQ-01A-PR

ICD O-3

Adenocarcinoma, tubular 8211/3

Site: Gastric cardia C16.0

W 3/7/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Cardia)

Product of resection of stomach, spleen and liver segments II and III.

- Moderately differentiated tubular gastric adenocarcinoma (intestinal type of Lauren) measuring 4.5 x 3.5 x 2.0 cm.
- Tumor involves the gastric body, cardia, esophagus and transposes all the gastric wall infiltrating the liver and the omentum.
- Presence of multiple tumoral implants in lesser and greater omentum.
- Presence of lymphatic and perineural infiltration.
- Non tumoral gastric mucosae exhibiting alkaline gastritis with areas presenting deep cystic gastritis.
- Proximal margin uninvolved by neoplasia, but only 3 mm distant from the tumor.
- Hepatic and distal margins uninvolved by neoplasia.
- Spleen uninvolved by neoplasia.
- Metastatic adenocarcinoma in the 2 of 6 lymph nodes dissected of the lesser curvature (2/6).
- 4 of 6 lymph nodes involved by metastatic adenocarcinoma of the greater curvature (4/6).

SPAA Discrepancy		✓
T or Malignancy Indistinct		✓
Case is Curable	✓	

Source: NCI Genomic Data Commons file 3b2902bf-fdaa-4aab-8e49-4ef0a08bbc3e (TCGA-VQ-A8PQ.0C2D93E8-2C88-4791-99E8-C050361755F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).